Somatic mutation profile of tumor specimen TCGA-AG-3731-01A (aliquot TCGA-AG-3731-01A-11D-1733-10) from TCGA case TCGA-AG-3731, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 65.5 years (23,923 days).
Specimen TCGA-AG-3731-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2e9cc6e-3f07-45bb-bac3-c45b87b92b3f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3731-11A (Solid Tissue Normal), aliquot TCGA-AG-3731-11A-01D-1733-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e3df99a-d1e6-45c9-a136-05a81c9b376a

The open-access MAF lists 159 somatic variants for this specimen: 117 protein-altering or splice-affecting, 40 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 98, Silent 40, Nonsense Mutation 10, Frame Shift Del 3, In Frame Del 3, RNA 2, Frame Shift Ins 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 32/129 reads (25%) | hotspot (GDC flag); catalogued as rs62619935, CM992133, COSV57320867; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 14/122 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.97-1G>A p.X33_splice | Splice Site (SNP) | VAF 11/27 reads (41%) | hotspot (GDC flag); catalogued as CS971912, COSV52665806, COSV52762622, COSV52838014; called by muse, mutect2, varscan2
- AACS | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1046993566, COSV55535598; called by muse, mutect2, varscan2
- AASDH | c.979G>A p.V327I | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as rs746388566, COSV52705387; called by muse, mutect2, varscan2
- AC011462.1 | c.22G>C p.E8Q | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); catalogued as COSV60531505; called by muse, mutect2, varscan2
- ADGRG4 | c.4984A>G p.T1662A | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV54952613; called by muse, mutect2, varscan2
- ADRA1A | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 25/92 reads (27%) | catalogued as COSV52359933; called by muse, mutect2, varscan2
- ALOX15 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs139214774; called by muse, mutect2, varscan2
- AMPH | c.210G>T p.M70I | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV57738162; called by muse, mutect2, varscan2
- AP3B2 | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs919136871, COSV55608085; called by muse, mutect2, varscan2
- ATAD3B | c.706C>T p.R236W (on ENST00000308647; = p.R342W on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs1557807620, COSV58019192; called by muse, mutect2
- BEST3 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56994200; called by muse, mutect2, varscan2
- CACNA1C | c.5347G>A p.G1783S | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as rs781633980, COSV59707133; called by muse, mutect2, varscan2
- CARMIL2 | c.722_724del p.M241del | In Frame Del (DEL) | VAF 23/129 reads (18%) | catalogued as rs768516975; called by pindel, varscan2
- CCNG1 | c.555A>T p.Q185H | Missense Mutation (SNP) | VAF 20/444 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV100243646; called by muse, mutect2
- CFHR5 | c.80A>G p.K27R | Missense Mutation (SNP) | VAF 20/341 reads (6%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.698); catalogued as COSV99889064; called by muse, mutect2
- CHAT | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs200176236, COSV60319829; ClinVar: uncertain significance; called by muse, varscan2
- CHST11 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766906152, COSV57985325; called by muse, mutect2, varscan2
- CIITA | c.2179G>A p.E727K | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs548646642, COSV60853941; called by muse, mutect2, varscan2
- CNTN5 | c.2665G>T p.V889L | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as COSV54296251; called by muse, mutect2, varscan2
- CORO1C | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV54594899; called by muse, mutect2, varscan2
- DSEL | c.2910A>T p.K970N | Missense Mutation (SNP) | VAF 47/207 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.705); catalogued as COSV59490409, COSV59493626; called by muse, mutect2, varscan2
- DZIP3 | c.236A>G p.D79G | Missense Mutation (SNP) | VAF 63/259 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as COSV64311592; called by muse, mutect2, varscan2
- EARS2 | c.1546C>T p.R516W | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769320749, CM167011, COSV99076831; called by mutect2, varscan2
- EHBP1L1 | c.1052C>T p.T351I | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.795); catalogued as COSV58572141; called by muse, mutect2, varscan2
- ENO2 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 137/264 reads (52%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.035); catalogued as rs151259229; called by muse, mutect2, varscan2
- EPB42 | c.1124C>T p.T375M (on ENST00000441366 / NM_001114134.2; = p.T405M on NM_000119.3) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs115972761, COSV55748610; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ERCC2 | c.2256G>T p.R752S | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV101228905; called by muse, varscan2
- ERGIC3 | c.462G>A p.K154= | Splice Region (SNP) | VAF 16/85 reads (19%) | catalogued as COSV54136586; called by muse, mutect2, varscan2
- FAT1 | c.6869del p.V2290Gfs*8 | Frame Shift Del (DEL) | VAF 53/144 reads (37%) | catalogued as COSV71673188; called by mutect2, pindel, varscan2
- FBXO8 | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 44/160 reads (28%) | catalogued as rs868785863, COSV67031153; called by muse, mutect2, varscan2
- FGF13 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1477376621, COSV59544138; called by muse, mutect2, varscan2
- FLRT1 | c.1045G>A p.V349M | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs779105954, COSV55358663; called by muse, mutect2, varscan2
- FMR1 | c.595A>G p.I199V | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV54422797; called by muse, mutect2, varscan2
- FNIP1 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764541101, COSV57195010; called by muse, mutect2, varscan2
- FRMPD4 | c.2183C>T p.A728V | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.049); catalogued as rs1294169574, COSV66213070; called by muse, mutect2, varscan2
- FUT5 | c.968A>G p.D323G | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs768406993, COSV99398833; called by muse, mutect2, varscan2
- GHR | c.1565C>T p.S522L | Missense Mutation (SNP) | VAF 41/289 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.044); catalogued as COSV100051103; called by muse, mutect2, varscan2
- GJA8 | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs140512440; called by muse, mutect2, varscan2
- GJC1 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs771348171, COSV57910785; called by muse, mutect2, varscan2
- GPRIN3 | c.545A>G p.K182R | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.294); catalogued as COSV60884515; called by muse, mutect2, varscan2
- GRM2 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.077); catalogued as rs147501226, COSV56583864; called by muse, mutect2, varscan2
- GTPBP4 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374244248; called by muse, mutect2, varscan2
- GUF1 | c.659A>G p.E220G | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.752); catalogued as COSV99877339; called by muse, mutect2, varscan2
- H4C1 | c.271C>T p.L91F | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.496); catalogued as COSV55119058; called by muse, mutect2, varscan2
- HECW2 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.991); catalogued as rs775414332, COSV53652950; called by muse, mutect2, varscan2
- HRG | c.1321C>T p.R441* | Nonsense Mutation (SNP) | VAF 11/104 reads (11%) | catalogued as rs370685538; called by muse, mutect2
- HTR2A | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66326953; called by muse, mutect2, varscan2
- ISG20 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs549880749, COSV60143590; called by muse, mutect2, varscan2
- ISLR | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs149796219, COSV51434720; called by muse, mutect2, varscan2
- KPNA3 | c.146G>C p.R49T | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55504029; called by muse, mutect2, varscan2
- LCE2B | c.139T>C p.C47R | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.955); catalogued as COSV64227559; called by muse, mutect2, varscan2
- LMNA | c.1487C>T p.T496M | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200466188, COSV61542319; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRP1B | c.4352C>G p.S1451* | Nonsense Mutation (SNP) | VAF 35/150 reads (23%) | catalogued as COSV101257880; called by muse, mutect2, varscan2
- LRRCC1 | c.1009T>C p.Y337H | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV64483053; called by muse, mutect2, varscan2
- LUM | c.575G>C p.S192T | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as COSV57127812, COSV57128059; called by muse, mutect2, varscan2
- MAP7D2 | c.1584G>C p.Q528H | Missense Mutation (SNP) | VAF 68/138 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV65526387; called by muse, mutect2, varscan2
- MAP7D3 | c.2254G>A p.D752N | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs753724897, COSV100286428; called by muse, mutect2, varscan2
- MAST3 | c.2893C>T p.R965W | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775231850, COSV53224177; called by mutect2, varscan2
- METTL14 | c.1182A>C p.R394S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.024); catalogued as COSV66310409; called by muse, mutect2, varscan2
- MIB1 | c.498A>T p.E166D | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.848); catalogued as COSV55089092; called by muse, mutect2, varscan2
- MMP2 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs368486758; called by muse, mutect2, varscan2
- MYH4 | c.4531C>T p.Q1511* | Nonsense Mutation (SNP) | VAF 23/71 reads (32%) | catalogued as rs545963911, COSV55115353; called by muse, mutect2, varscan2
- MYO9A | c.1949T>A p.I650K | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61849186, COSV61849485; called by muse, mutect2, varscan2
- NDUFS2 | c.421T>G p.Y141D | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100917488; called by muse, mutect2
- NEK10 | c.2413C>G p.L805V | Missense Mutation (SNP) | VAF 29/256 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.24); catalogued as rs1430524826, COSV55356920; called by muse, mutect2, varscan2
- NFATC2 | c.1640G>A p.R547Q | Missense Mutation (SNP) | VAF 46/227 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65358254; called by muse, varscan2
- NGLY1 | c.1634G>T p.G545V | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54985234; called by muse, mutect2, varscan2
- NRCAM | c.3059T>C p.F1020S (on ENST00000379028 / NM_001371124.1; = p.F1004S on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV61033637; called by muse, mutect2, varscan2
- NSMAF | c.1283T>C p.I428T | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV50685238; called by muse, mutect2, varscan2
- NUAK2 | c.375_378del p.V126Sfs*132 | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | catalogued as COSV65681117; called by mutect2, pindel, varscan2
- NUP214 | c.5849G>A p.G1950E | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63908517; called by muse, mutect2, varscan2
- OR10AG1 | c.428C>A p.T143K | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV56632236; called by muse, mutect2, varscan2
- OR10T2 | c.715G>T p.V239F | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV57781301; called by muse, mutect2, varscan2
- PCDHA3 | c.1663G>A p.V555M | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV63539756; called by muse, mutect2, varscan2
- PHF21B | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs767031532, COSV57557176; called by muse, mutect2, varscan2
- PLAG1 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57610227; called by muse, mutect2, varscan2
- PNOC | c.35G>A p.S12N | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as COSV57283271; called by muse, mutect2, varscan2
- PPAT | c.1181G>A p.R394K | Missense Mutation (SNP) | VAF 74/381 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99947328; called by muse, mutect2, varscan2
- PTPRK | c.3944T>A p.F1315Y (on ENST00000368215 / NM_001291984.2; = p.F1316Y on NM_002844.4) | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63894319; called by muse, mutect2, varscan2
- RAB29 | c.439G>A p.G147S | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as rs1372871032, COSV52520894; called by muse, mutect2, varscan2
- REXO1 | c.1210C>T p.R404* | Nonsense Mutation (SNP) | VAF 21/129 reads (16%) | catalogued as COSV50076039; called by muse, mutect2, varscan2
- RUNX1T1 | c.312_314del p.S108del (on ENST00000265814 / NM_001198628.1; = p.S81del on NM_004349.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 24/86 reads (28%) | catalogued as rs1411198690; called by pindel, varscan2
- SAMD15 | c.1313A>G p.E438G | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as COSV53625903; called by muse, mutect2, varscan2
- SAMD9L | c.4406C>T p.S1469F | Missense Mutation (SNP) | VAF 74/324 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV59080579; called by muse, mutect2, varscan2
- SEC24C | c.3133C>T p.R1045W | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as rs756251861, COSV100226956; called by muse, mutect2, varscan2
- SETD2 | c.5500G>A p.V1834I | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs760392790, COSV100339283; called by muse, mutect2, varscan2
- SLC35F4 | c.608C>T p.T203I (on ENST00000339762 / NM_001352015.2; = p.T167I on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV60263655; called by muse, mutect2, varscan2
- SLC7A3 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs766296825, COSV53227007, COSV53228191; called by muse, mutect2, varscan2
- SLCO1B1 | c.779T>G p.L260R | Missense Mutation (SNP) | VAF 105/695 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99918652; called by muse, mutect2, varscan2
- SPAG9 | c.3838G>A p.D1280N (on ENST00000262013 / NM_001130528.3; = p.D1266N on NM_003971.6) | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs778025223, COSV56233514; called by muse, mutect2, varscan2
- SPECC1 | c.2857C>G p.L953V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs776916403, COSV54955637; called by muse, mutect2, varscan2
- SYNE1 | c.7829G>C p.R2610T (on ENST00000367255 / NM_182961.4; = p.R2617T on NM_033071.3) | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as COSV99568480; called by muse, mutect2, varscan2
- TAGAP | c.1380C>G p.F460L | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57851038; called by muse, mutect2, varscan2
- TENM1 | c.6773C>T p.A2258V | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.647); catalogued as rs372260419, COSV64428572; called by muse, mutect2, varscan2
- TNRC6A | c.3928C>G p.Q1310E | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV59362660; called by muse, mutect2, varscan2
- TOR1A | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.821); catalogued as COSV52212775; called by muse, mutect2, varscan2
- TRANK1 | c.8606A>G p.N2869S | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.79); PolyPhen benign (0.026); catalogued as COSV57145630; called by muse, mutect2, varscan2
- TRIP6 | c.1249A>T p.R417* | Nonsense Mutation (SNP) | VAF 41/194 reads (21%) | catalogued as COSV52341406; called by muse, mutect2, varscan2
- TTN | c.22422C>G p.F7474L (on ENST00000591111; = p.F6547L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/97 reads (15%) | PolyPhen benign (0.005); catalogued as COSV59964382; called by muse, mutect2, varscan2
- UNC13C | c.3692G>T p.G1231V | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52856892; called by muse, mutect2, varscan2
- WNK3 | c.1031C>T p.S344L | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV63612844; called by muse, mutect2, varscan2
- XAB2 | c.666C>A p.H222Q | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV64321454; called by muse, mutect2, varscan2
- YEATS4 | c.6C>G p.F2L | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.01); catalogued as rs1362119645, COSV56088496; called by muse, mutect2, varscan2
- ZC3H18 | c.2045G>A p.R682Q | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.873); catalogued as rs1327530688, COSV56323769; called by muse, mutect2, varscan2
- ZC3HAV1 | c.1533A>C p.E511D | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as COSV54294495; called by muse, mutect2, varscan2
- ZFPM2 | c.2510T>G p.L837* | Nonsense Mutation (SNP) | VAF 8/126 reads (6%) | catalogued as COSV104429043, COSV65873008; called by muse, mutect2
- ZFYVE26 | c.1531C>T p.L511F | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.927); catalogued as rs1199391936, COSV61326228; called by muse, mutect2, varscan2
- ZIC1 | c.738C>G p.F246L | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV51552170, COSV51556900; called by muse, mutect2, varscan2
- ZNF490 | c.1541C>G p.S514* | Nonsense Mutation (SNP) | VAF 24/111 reads (22%) | catalogued as COSV61007532; called by muse, mutect2, varscan2
- ZNF626 | c.907C>T p.H303Y | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV74129225; called by muse, mutect2, varscan2
- ZSCAN20 | c.314G>A p.R105K | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV100792505, COSV63682082; called by muse, mutect2, varscan2
- GPHN | c.1013dup p.V339Gfs*44 (on ENST00000315266 / NM_001377519.1; = p.V372Gfs*44 on NM_020806.5) | Frame Shift Ins (INS) | VAF 14/95 reads (15%) | called by mutect2, pindel, varscan2
- IKBKG | c.838G>A p.V280M | Missense Mutation (SNP) | VAF 38/181 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.051); called by muse, mutect2
- SZT2 | c.5877del p.E1961Rfs*85 (on ENST00000634258 / NM_001365999.1; = p.E1904Rfs*85 on NM_015284.4) | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | called by mutect2, pindel, varscan2
- TAS2R3 | c.614_616del p.F205del | In Frame Del (DEL) | VAF 28/138 reads (20%) | called by pindel, varscan2
- ADORA2A | c.438C>T p.C146= | Silent (SNP) | VAF 38/134 reads (28%) | catalogued as rs780091269, COSV58378398; called by muse, mutect2, varscan2
- BCL3 | c.1224C>A p.P408= | Silent (SNP) | VAF 53/239 reads (22%) | catalogued as COSV51233997, COSV51234135; called by muse, mutect2, varscan2
- BRAF | c.969G>A p.S323= | Silent (SNP) | VAF 37/144 reads (26%) | catalogued as rs768134774, COSV56077202; called by muse, mutect2, varscan2
- DENND4B | c.1995G>A p.P665= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs1238914438, COSV100768752; called by muse, mutect2, varscan2
- DICER1 | c.4623G>A p.K1541= | Silent (SNP) | VAF 7/148 reads (5%) | called by muse, mutect2
- DNAH10 | c.5691C>T p.T1897= (on ENST00000409039; = p.T1836= on NM_207437.3) | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as rs202158921; called by muse, mutect2, varscan2
- DRC1 | c.1113G>A p.S371= | Silent (SNP) | VAF 15/100 reads (15%) | catalogued as rs145445723; called by muse, mutect2, varscan2
- DRD2 | c.150C>T p.F50= | Silent (SNP) | VAF 41/154 reads (27%) | catalogued as rs767660986, COSV100670313, COSV60761652; called by muse, mutect2, varscan2
- FAM47C | c.456G>A p.P152= | Silent (SNP) | VAF 42/81 reads (52%) | catalogued as rs782651418, COSV63725345, COSV63730617; called by muse, mutect2, varscan2
- FGF11 | c.624G>A p.E208= | Silent (SNP) | VAF 34/92 reads (37%) | catalogued as COSV99548372; called by muse, mutect2, varscan2
- HHAT | c.510G>A p.Q170= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as COSV54795507; called by muse, mutect2
- HOXC8 | c.507C>G p.L169= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV50000873; called by muse, mutect2, varscan2
- KCNA5 | c.1545C>T p.I515= | Silent (SNP) | VAF 18/250 reads (7%) | catalogued as rs1429404337, COSV52904695; called by muse, mutect2
- KCNS3 | c.624G>A p.S208= | Silent (SNP) | VAF 35/130 reads (27%) | catalogued as rs140824188; called by muse, mutect2, varscan2
- KDM1A | c.1200C>T p.V400= | Silent (SNP) | VAF 16/146 reads (11%) | catalogued as COSV63087220; called by muse, mutect2, varscan2
- LRP2 | c.11412G>A p.Q3804= | Silent (SNP) | VAF 36/126 reads (29%) | catalogued as COSV55547337; called by muse, mutect2, varscan2
- LRRN4 | c.1713C>A p.P571= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV66644937; called by muse, mutect2, varscan2
- MOV10L1 | c.438C>T p.C146= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as rs757077590, COSV53169091; called by muse, mutect2, varscan2
- MPIG6B | c.414C>T p.S138= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs753090851, COSV65389505; called by muse, mutect2, varscan2
- MTR | c.2952C>G p.L984= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV100855416; called by muse, mutect2, varscan2
- NAXD | c.336C>T p.A112= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as rs753399080, COSV59394005; called by muse, mutect2, varscan2
- OR4K5 | c.186C>A p.L62= | Silent (SNP) | VAF 62/285 reads (22%) | catalogued as COSV60002861; called by muse, mutect2, varscan2
- PCDHA1 | c.2091C>T p.N697= | Silent (SNP) | VAF 49/202 reads (24%) | catalogued as COSV65373447; called by muse, mutect2, varscan2
- PIWIL1 | c.459C>T p.H153= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as rs766051497, COSV99806237; called by muse, mutect2, varscan2
- POLN | c.486T>C p.N162= | Silent (SNP) | VAF 33/270 reads (12%) | catalogued as COSV67024303; called by muse, mutect2, varscan2
- PSKH2 | c.171C>T p.P57= | Silent (SNP) | VAF 27/247 reads (11%) | catalogued as COSV52609877; called by muse, mutect2, varscan2
- PTDSS2 | c.393G>A p.V131= | Silent (SNP) | VAF 99/431 reads (23%) | catalogued as COSV100339326, COSV57277681; called by muse, mutect2, varscan2
- REG3A | c.441G>A p.A147= | Silent (SNP) | VAF 26/110 reads (24%) | catalogued as rs764024027, COSV59408168, COSV59409006; called by muse, mutect2, varscan2
- SNTA1 | c.1275G>A p.V425= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV99458759; called by muse, mutect2, varscan2
- SPATA6L | c.78T>C p.D26= | Silent (SNP) | VAF 32/139 reads (23%) | catalogued as rs749642693, COSV56304875; called by muse, mutect2, varscan2
- SPTA1 | c.4830G>A p.Q1610= | Silent (SNP) | VAF 53/386 reads (14%) | catalogued as COSV100935121; called by muse, mutect2, varscan2
- TM9SF4 | c.429G>A p.R143= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV54105682; called by muse, mutect2, varscan2
- TRPS1 | c.2178C>T p.G726= (on ENST00000220888 / NM_001330599.2; = p.G739= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 56/272 reads (21%) | catalogued as COSV99631792; called by muse, mutect2, varscan2
- TTF1 | c.813C>T p.H271= | Silent (SNP) | VAF 9/99 reads (9%) | catalogued as COSV57506110; called by muse, mutect2
- UBE2G2 | c.291C>T p.G97= | Silent (SNP) | VAF 4/51 reads (8%) | catalogued as rs782152223, COSV100446125, COSV100446185; called by muse, mutect2
- UCMA | c.18C>T p.A6= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs187657704, COSV66321426; called by muse, mutect2, varscan2
- USP24 | c.1233C>T p.T411= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV53765099; called by muse, mutect2, varscan2
- VAPB | c.63C>T p.P21= | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as rs1211879173, COSV55666904; called by muse, mutect2, varscan2
- ZNF134 | c.228A>G p.K76= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs373945795; called by muse, mutect2, varscan2
- ZNF253 | c.465G>A p.K155= | Silent (SNP) | VAF 38/157 reads (24%) | catalogued as COSV63036813; called by muse, mutect2, varscan2
- MIR124-2 | n.71C>T | RNA (SNP) | VAF 14/84 reads (17%) | called by muse, mutect2, varscan2
- ZNF658B | n.946G>T | RNA (SNP) | VAF 26/300 reads (9%) | called by muse, mutect2, varscan2
